Somatic mutation profile of tumor specimen TCGA-HT-7689-01A (aliquot TCGA-HT-7689-01A-11D-2253-08) from TCGA case TCGA-HT-7689, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 58.4 years (21,331 days).
Specimen TCGA-HT-7689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 412f371a-0007-4da5-b004-6a15bc73aafc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7689-10A (Blood Derived Normal), aliquot TCGA-HT-7689-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43fdb219-d31e-43be-b173-361341a82bca

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 33, Silent 9, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/128 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4629T>G p.I1543M | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV70032334; called by muse, mutect2
- ANK1 | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601925, COSV55876028, COSV55884544; called by muse, mutect2, varscan2
- BSN | c.5149A>T p.N1717Y | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56520788; called by muse, mutect2
- C16orf46 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV55151630; called by muse, mutect2
- DCAF12L2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1374590191, COSV63580149; called by muse, mutect2
- DMXL2 | c.7156G>A p.G2386R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51848635; called by muse, mutect2
- EIF2B4 | c.310C>T p.R104C (on ENST00000347454 / NM_001034116.2; = p.R103C on NM_015636.3) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV52007503; called by muse, mutect2, varscan2
- ENPP3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV62954755; called by muse, mutect2, varscan2
- EXPH5 | c.5370C>A p.H1790Q | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV56203758; called by muse, mutect2
- FAT2 | c.5894G>T p.S1965I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as COSV55822133; called by muse, mutect2, varscan2
- FAT4 | c.3044T>C p.F1015S | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67889684; called by muse, mutect2
- GDPD2 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.15); catalogued as rs1407642600, COSV65533261; called by muse, mutect2, varscan2
- GRIA3 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 39/339 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52066676; called by muse, mutect2, varscan2
- ITIH4 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV56575382; called by muse, mutect2, varscan2
- ITPR3 | c.6461G>A p.R2154Q | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs756358608, COSV65410938; called by muse, mutect2, varscan2
- KIF21A | c.545C>G p.T182S | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62772928; called by muse, mutect2
- LAMC3 | c.1987C>T p.L663F | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.049); catalogued as COSV63092477; called by muse, mutect2, varscan2
- MAP7 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774931261, COSV63417327; called by muse, mutect2, varscan2
- MROH2B | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV68185497, COSV68186879; called by muse, mutect2
- NEURL1 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as COSV63507846, COSV63510742; called by muse, mutect2
- OBSCN | c.17899C>T p.R5967C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs919675899, COSV52785484; called by muse, mutect2, varscan2
- OOSP2 | c.98T>A p.V33D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53929199; called by muse, mutect2, varscan2
- PCDHA11 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56514278; called by muse, mutect2, varscan2
- PPP2R3A | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53865582; called by muse, mutect2, varscan2
- PROKR1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769119228, COSV58137559; called by muse, mutect2, varscan2
- RAB17 | c.531C>T p.A177= | Splice Region (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52815067, COSV52816152; called by muse, mutect2, varscan2
- RAPGEF6 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV57248546; called by muse, mutect2, varscan2
- RILPL1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV61553141; called by muse, mutect2, varscan2
- SLC17A5 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as rs199727701, COSV63287679; called by muse, mutect2, varscan2
- SPTLC3 | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.019); catalogued as COSV65466389; called by muse, mutect2, varscan2
- SRCAP | c.3484C>G p.P1162A | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV52674917; called by muse, varscan2
- TUBB4B | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV61117234; called by muse, mutect2, varscan2
- ATRX | c.1109dup p.Y370* | Nonsense Mutation (INS) | VAF 49/179 reads (27%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.5630_5633del p.I1877Kfs*35 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- GABRA3 | c.1317G>A p.V439= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as COSV64800435; called by muse, mutect2, varscan2
- JAG1 | c.2445C>T p.P815= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs777122869, COSV54758336; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNK13 | c.729G>A p.L243= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV56414091; called by muse, mutect2, varscan2
- MLPH | c.1350C>T p.D450= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs773144090, COSV52821384; called by muse, mutect2, varscan2
- MTFMT | c.714G>A p.A238= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54978295; called by muse, mutect2, varscan2
- MUC16 | c.2493G>A p.S831= | Silent (SNP) | VAF 49/299 reads (16%) | catalogued as rs764383339, COSV67454733; called by muse, mutect2, varscan2
- PITPNM3 | c.717A>T p.R239= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV52596628; called by muse, mutect2, varscan2
- SEL1L2 | c.180A>C p.V60= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV53153697; called by muse, mutect2
- SRCAP | c.4125C>G p.L1375= | Silent (SNP) | VAF 90/298 reads (30%) | catalogued as COSV52670428, COSV52674928; called by muse, mutect2, varscan2
